Gene-level copy-number profile of tumor specimen SM-JU334 from CPTAC case C464694, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Frontal lobe; Tumor grade: G4.
Specimen SM-JU334: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 324984fe-340c-4cfa-8ab1-0931a3e36087.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105273 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/756458d1-f7d1-4db0-9d50-012947c362f9

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 244; copy number 2: 1,418; copy number 3: 10,075; copy number 4: 45,972; copy number 5: 450; copy number 6: 112; copy number 10: 3; copy number 11: 2; copy number 18: 2; copy number 24: 1; copy number 34: 7; copy number 35: 2; copy number 36: 11; copy number 37: 31; copy number 38: 7; copy number 67: 13; copy number 70: 31.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:4,233,288–4,288,083, 4 genes: SSU72P5, SSU72P2, SSU72P6, SSU72P4.
- chr11:55,602,360–55,686,160, 7 genes: OR4C11, OR4P4, OR4S2, OR4C6, OR4V1P, OR4P1P, AP006437.1.
- chr17:18,452,955–18,453,739, 2 genes (within-gene range 0–1): AL353997.1, AL353997.4.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 110 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,500,512, 5 genes, copy number 10–11: AC239859.5, RNA5SP533, AC239859.3, AC239859.2, LINC02799.
- chr12:4,909,867–5,026,012, 2 genes, copy number 18 (within-gene range 4–18): AC005906.2, KCNA1.
- chr12:31,012,503–31,369,301, 15 genes, copy number 37: AC008013.2, DDX11-AS1, DDX11, SNORA75, AC008013.3, AC024940.1, AC024940.4, AC024940.2, MREGP1, AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6.
- chr12:33,923,374–33,982,566, 2 genes, copy number 36: RNU6-472P, Y_RNA.
- chr12:52,164,115–52,229,588, 4 genes, copy number 36: LINC00592, KRT80, LINC02874, METTL7AP1.
- chr12:57,674,665–58,105,935, 31 genes, copy number 70: RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2.
- chr12:64,709,458–65,248,355, 15 genes, copy number 35–67: AC025262.1, GNS, TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2.
- chr12:69,584,722–69,699,476, 6 genes, copy number 34: MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3.
- chr12:71,754,863–71,800,286, 2 genes, copy number 38: RAB21, AC089984.1.
- chr12:75,234,740–75,511,636, 10 genes, copy number 37: CAPS2-AS1, CCNG2P1, CAPS2, AC092552.1, AC121761.2, GLIPR1L1, GLIPR1L2, GLIPR1, AC121761.1, KRR1.
- chr12:93,266,017–93,441,947, 5 genes, copy number 36: AC126172.1, AC124947.2, AC124947.1, NUDT4, UBE2N.
- chr12:98,113,014–98,318,349, 2 genes, copy number 37: AC016152.1, AC008055.1.
- chr12:102,012,840–102,062,149, 1 gene, copy number 37: WASHC3.
- chr12:103,237,591–103,495,978, 1 gene, copy number 38 (within-gene range 4–38): C12orf42.
- chr12:104,976,749–104,978,027, 1 gene, copy number 37: KRT18P20.
- chr12:107,271,394–107,659,642, 4 genes, copy number 38 (within-gene range 3–38): SETP7, BTBD11, AC009774.1, RNA5SP371.
- chr12:112,405,190–112,418,838, 1 gene, copy number 24 (within-gene range 4–24): RPL6.
- chr12:113,298,759–113,426,301, 3 genes, copy number 34–37 (within-gene range 5–37): SLC8B1, PLBD2, SDS.

Autosomal genes at a single copy (total copy number 1): 244. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
